Surgical pathology report (de-identified scan), TCGA case TCGA-TP-A8TV, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Maine Medical Center, specimen TCGA-TP-A8TV-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
9/11/27/14

FINAL DIAGNOSIS:

(A) Lymph node, left pelvic; excision: Small single benign lymph node

(B) Lymph nodes, right pelvic; excision: Three benign lymph nodes

(C) Prostate; radical prostatectomy: Adenocarcinoma of the prostate

pTNM classification (based on available surgical material): pT2c, pN0.

Histologic type: Adenocarcinoma.

Gleason grade: 4 + 3 = 7/10 (please see comment).

Percent Gleason grades 4 and 5: 75% and <5%, respectively.

Tumor location: All four quadrants involved by tumor (comprising approximately 15%).

Maximal tumor diameter: Approximately 2.0 cm.

Vascular invasion: Not definitively seen.

Extraprostatic extension: Absent.

Resection margins: Positive for malignancy in the right anterior base region (spanning an area of 3 mm).

Seminal vesicles: Negative for malignancy.

Third Gleason pattern: Present (pattern 5, comprising <5%).

Tumor multicentricity: Present.

Premalignant changes: High-grade PIN.

Non-neoplastic changes: Nodular hyperplasia. Acute prostatitis.

Lymph nodes: Please see separate specimens above (0/4).

Representative tumor blocks: C6-10.

Other findings or comments: A dominant tumor nodule is present in the right anterior region, showing predominantly 4+4 Gleason pattern with focal tertiary Gleason 5.

(D) Bladder neck margin; excision: Negative for malignancy

CLINICAL HISTORY: Malignant neoplasm of prostate.

GROSS DESCRIPTION:

(A) The specimen is received unfixed labeled _____ L pelvic node and is a piece of soft, fatty tissue measuring 1.0 x 1.0 x 0.4 cm. The entire specimen is submitted.

(B) The specimen is received unfixed labeled _____ and rt. Pelvic lymph nodes and are three lymph nodes ranging in size from 0.5 to 0.7 cm.

(C) The specimen is received unfixed labeled _____ and prostate. It is a prostate gland with attached seminal vesicles. It weighs 32 grams and measures 4.0 x 3.8 x 3.8 cm. The right seminal vesicle measures 2.5 x 0.7 x 0.4 cm. The left seminal vesicle measures 2.6 x 0.8 x 0.4 cm. The right anterior prostate is marked with orange ink, right posterior prostate marked with blue ink, left anterior prostate marked with black ink, left posterior prostate marked with green ink. Sectioning shows a right-sided poorly defined mass measuring 2.0 x 1.6 x 1.6 cm. Sections are submitted as follows:

1. Right seminal vesicle;
2. Left seminal vesicle;
- 3+4. Apex, coned;
5. Proximal margin, coned;
- 6-10. Right anterior prostate, apex to base;

[page 2 of 2]
- 11-15. Right posterior prostate, apex to base;
16-20. Left anterior prostate, apex to base;
21-25. Left posterior prostate, apex to base. , 25 cassettes)

(D) The specimen is received in formalin _____ and bladder neck margin. The specimen consists of a 0.5 cm pink-tan tissue fragment. (1 cassette)

Source: NCI Genomic Data Commons file b8c2859e-a0e8-42ae-b140-0d53614a4f5b (TCGA-TP-A8TV.5B38DF20-A6AF-4CD7-9322-36D4823C7A3E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).